Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3902, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3902-01A (Primary Tumor).

Diagnosis/ diagnoses

1. Resected colon (rectosigmoid) with tumor-free oral and aboral resection margins, with two tubular adenomas, with moderate dysplasia and including an ulcerated, moderately differentiated adenocarcinoma with infiltration of the perimuscular fatty tissue and without local lymph node metastases (G2, pT3 pN0 0/17 L0 V0 R0).
2. Splenectomy preparation with recent capsule and parenchymal defects with, according to clinical data, a condition following iatrogenic injury.

Source: NCI Genomic Data Commons file 4d7718ae-8cd3-4651-83c4-f0228dffb30f (TCGA-AG-3902.6453365C-AEC8-4E53-B779-A15AF390D61E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).